Gene-level copy-number profile of tumor specimen TCGA-60-2723-01A from TCGA case TCGA-60-2723, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.5 years (27,225 days).
Specimen TCGA-60-2723-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d726b5b8-a5ee-47e0-9a41-9ee62da01b73.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2723-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bac60d27-86cf-401b-ab89-fa573cfa7f36

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,010; copy number 2: 31,148; copy number 3: 14,507; copy number 4: 6,177; copy number 5: 2,083; copy number 6: 4,477; copy number 7: 39; copy number 8: 180; copy number 11: 13; copy number 13: 39; copy number 14: 103; copy number 15: 7; copy number 21: 5; copy number 46: 4; copy number 67: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-60-2723-01A-01D-0844-01): tumor purity 0.39, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,971 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–10,630,758, 359 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:17,510,584–70,125,317, 897 genes, copy number 5 (broad region; genes not listed).
- chr2:229,606,238–242,160,153, 324 genes, copy number 5 (broad region; genes not listed).
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 6 (broad region; genes not listed).
- chr4:55,595,229–55,636,698, 1 gene, copy number 6: NMU.
- chr4:115,628,812–117,085,576, 19 genes, copy number 6–11: RPF2P2, PGAM4P2, KRT18P21, AC027613.1, EIF3KP3, TTC39CP1, MTRNR2L13, MIR1973, TRMT112P1, CUL4AP1, AC106892.1, ACTN4P1, AC093765.5, AC093765.4, AC093765.3, AC093765.2, RNU6-119P, AC093765.1, TRAM1L1.
- chr5:58,198–45,895,970, 710 genes, copy number 6–11 (broad region; genes not listed).
- chr6:67,210,408–71,652,611, 57 genes, copy number 6: AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3, LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, AL096709.1, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.2, AL035467.1, KRT19P1, RNU4-66P.
- chr7:70,972–26,995,239, 430 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr7:27,092,993–31,708,455, 127 genes, copy number 6 (broad region; genes not listed).
- chr8:121,113,358–145,066,685, 448 genes, copy number 5 (broad region; genes not listed).
- chr9:4,792,944–6,645,729, 50 genes, copy number 7–13 (within-gene range 1–13): RCL1, MIR101-2, AL158147.1, HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1.
- chr9:8,700,595–8,797,194, 3 genes, copy number 7: AL583805.2, AL583805.1, RNU7-185P.
- chr9:10,532,145–12,823,060, 18 genes, copy number 5–15: AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L.
- chr11:11,781,971–11,811,530, 1 gene, copy number 5 (within-gene range 1–5): AC104383.1.
- chr11:11,841,423–14,643,635, 51 genes, copy number 5 (within-gene range 4–5): USP47, H3P33, DKK3, LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1, PARVA, AC009806.1, AC107881.1, TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1.
- chr11:25,630,720–26,047,598, 4 genes, copy number 13: AC100770.1, LINC02699, AC013799.1, AC024341.1.
- chr11:26,244,640–26,331,289, 2 genes, copy number 13: AC021698.1, ANO3-AS1.
- chr11:55,935,456–56,543,281, 53 genes, copy number 6: OR5I1, OR10AF1P, OR10AK1P, OR10AG1, OR7E5P, OR5F1, OR5F2P, OR5AS1, OR5AQ1P, OR5J1P, OR5BE1P, OR8I2, OR8I4P, OR8H2, OR5BN2P, OR8H3, OR5BN1P, OR8J3, OR8K4P, OR8K5, OR5J7P, OR5J2, OR8V1P, AC022882.1, OR8J2, OR5T2, OR5T3, OR5T1, OR8H1, OR8I1P, OR8K3, FAM8A2P, OR8K2P, OR8K1, OR8J1, RPL5P29, OR8U1, OR8L1P, OR5AL2P, OR5AL1, OR5R1, OR5M4P, AP002512.3, OR5M9, OR5M3, OR5M2P, OR5M8, AP002512.1, OR5M7P, AP002512.2, OR5M6P, OR5M5P, OR5M11.
- chr11:57,712,582–57,818,431, 1 gene, copy number 6 (within-gene range 4–6): AP001931.2.
- chr11:57,741,250–58,216,084, 23 genes, copy number 6: SELENOH, AP001931.1, BTBD18, CTNND1, OR5BA1P, AP003484.1, OR5AZ1P, OR5BD1P, CYCSP26, OR9Q1, RNU6-899P, OR6Q1, VN2R9P, AP004247.2, AP004247.1, OR9L1P, OR9I3P, OR9I1, OR9I2P, OR5BL1P, OR9Q2, OR1S2, OR1S1.
- chr12:38,532,895–40,369,285, 23 genes, copy number 6: AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1.
- chr12:40,395,853–40,443,847, 1 gene, copy number 6 (within-gene range 2–6): AC107023.1.
- chr12:63,271,404–71,441,898, 177 genes, copy number 6–67 (broad region; genes not listed).
- chr12:71,448,405–71,448,850, 1 gene, copy number 14: AC090116.1.
- chr14:23,293,852–23,435,660, 15 genes, copy number 7: H3P37, PPP1R3E, BCL2L2, BCL2L2-PABPN1, PABPN1, SLC22A17, EFS, AL049829.2, IL25, CMTM5, MYH6, MIR208A, MYH7, AL132855.1, MIR208B.
- chr22:15,290,718–50,801,309, 1,376 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,010. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
